Somatic mutation profile of tumor specimen TCGA-WC-A888-01A (aliquot TCGA-WC-A888-01A-11D-A39W-08) from TCGA case TCGA-WC-A888, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.0 years (28,117 days).
Specimen TCGA-WC-A888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86409bac-e82b-4bc4-bcdd-c92ffad93552.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A888-10A (Blood Derived Normal), aliquot TCGA-WC-A888-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01d55946-ac37-40d0-b5d4-d4e418604cb5

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM156459, COSV56231551, COSV56238100; called by muse, mutect2
- CACNA1B | c.6773C>T p.P2258L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1430690049; called by muse, mutect2, varscan2
- CADM3 | c.266C>T p.T89M (on ENST00000368125 / NM_001127173.3; = p.T123M on NM_021189.5) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748945624, COSV63684507; called by muse, mutect2, varscan2
- CFAP70 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302123744; called by muse, mutect2, varscan2
- GPR78 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1014333637; called by muse, mutect2, varscan2
- OR5B21 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1239622308; called by muse, mutect2, varscan2
- OSM | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs149963275; called by muse, mutect2, varscan2
- SPAG16 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs747474099, COSV100531553; called by muse, mutect2, varscan2
- SPAG5 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as rs756148727; called by muse, mutect2, varscan2
- SPTBN1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61685379, COSV61690403; called by muse, mutect2
- THBS1 | c.157del p.D53Tfs*14 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | catalogued as COSV52949951; called by mutect2, pindel, varscan2
- ARAP3 | c.68A>C p.D23A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIR2DL4 | c.1091C>T p.T364I (on ENST00000396284; = p.T290I on NM_001080770.2) | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.27); called by muse, mutect2
- LIPI | c.671C>A p.A224E | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRSF2 | c.519_536del p.S174_S179del | In Frame Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel
- DDR2 | c.1236C>T p.L412= | Silent (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- DENND6A | c.1122T>C p.L374= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, varscan2
- OR9A4 | c.54C>A p.G18= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
